Somatic mutation profile of tumor specimen TCGA-NA-A5I1-01A (aliquot TCGA-NA-A5I1-01A-21D-A28R-08) from TCGA case TCGA-NA-A5I1, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIB; Age at diagnosis: 80.3 years (29,329 days).
Specimen TCGA-NA-A5I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acb39477-bc77-4faf-b9f9-6507d27d3ddf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NA-A5I1-10A (Blood Derived Normal), aliquot TCGA-NA-A5I1-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10254c73-710d-4cd0-8d60-fc68ea71e827

The open-access MAF lists 44 somatic variants for this specimen: 37 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 30, Silent 7, Nonsense Mutation 3, Splice Region 1, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTFL1 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as rs769327864, COSV56111379; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 32/37 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.1395G>A p.P465= | Splice Region (SNP) | VAF 24/107 reads (22%) | catalogued as rs373855918; called by muse, mutect2, varscan2
- ANKRD52 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs777966459; called by muse, mutect2, varscan2
- APOBEC1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1353444746, COSV57550193; called by muse, mutect2, varscan2
- CNOT1 | c.6164C>G p.T2055R | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV55315252; called by muse, mutect2, varscan2
- COL20A1 | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs745828746, COSV58926505; called by muse, mutect2, varscan2
- COL24A1 | c.4600C>T p.P1534S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65313966; called by muse, mutect2, varscan2
- DOCK10 | c.5858C>T p.T1953M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs777792020, COSV51393285; called by muse, mutect2, varscan2
- EPDR1 | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771376229, COSV52260137; called by muse, mutect2, varscan2
- GPATCH2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757315065, COSV99055531; called by muse, mutect2, varscan2
- ITGA3 | c.3137G>A p.R1046K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.293); catalogued as rs1287525565; called by muse, mutect2, varscan2
- KRTAP10-7 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59113617; called by muse, mutect2
- LRP1B | c.324C>G p.D108E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766907792, COSV67194820, COSV67252815; called by muse, mutect2, varscan2
- LRP2 | c.11522A>G p.Y3841C | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1485924197; called by muse, mutect2
- NLRP10 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs900658112, COSV60778448; called by muse, mutect2, varscan2
- P3H2 | c.1919G>T p.R640L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765123377; called by muse, mutect2, varscan2
- ZMYM1 | c.3181A>G p.S1061G | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs760542178, COSV100720886; called by muse, mutect2, varscan2
- ACE2 | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 189/418 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CERS6 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLCN1 | c.2912A>T p.Q971L | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CTCFL | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DHX8 | c.1676T>A p.L559H | Missense Mutation (SNP) | VAF 167/242 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DNAH8 | c.12183+2T>C p.X4061_splice | Splice Site (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- IER3 | c.253del p.R85Gfs*15 | Frame Shift Del (DEL) | VAF 87/218 reads (40%) | called by mutect2, pindel, varscan2
- INSC | c.1532G>C p.S511T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- IRS4 | c.3518A>T p.E1173V | Missense Mutation (SNP) | VAF 112/257 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ITGA7 | c.3412_3414del p.E1138del (on ENST00000555728; = p.E1094del on NM_002206.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 31/70 reads (44%) | called by pindel, varscan2
- LRRC36 | c.1217T>A p.F406Y | Missense Mutation (SNP) | VAF 161/169 reads (95%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NCKAP5 | c.3152G>C p.R1051P | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51A2 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- P2RX6 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 94/105 reads (90%) | called by muse, mutect2, varscan2
- PDCD5 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- PDGFRB | c.2851T>A p.F951I | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A13 | c.409C>G p.R137G | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SULT2A1 | c.543A>T p.L181F | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.018); called by muse, mutect2
- AHNAK | c.9948C>G p.P3316= | Silent (SNP) | VAF 26/47 reads (55%) | called by muse, mutect2, varscan2
- DTNA | c.1350G>C p.S450= | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- FLG | c.8664A>C p.G2888= | Silent (SNP) | VAF 153/686 reads (22%) | called by muse, mutect2, varscan2
- FLG2 | c.4512C>T p.S1504= | Silent (SNP) | VAF 96/316 reads (30%) | catalogued as rs1175808482; called by muse, mutect2, varscan2
- HSPBP1 | c.411C>T p.A137= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1300310999, COSV55333521; called by muse, mutect2, varscan2
- MBNL3 | c.114C>A p.A38= | Silent (SNP) | VAF 43/222 reads (19%) | called by muse, mutect2, varscan2
- SCNN1B | c.726C>G p.G242= | Silent (SNP) | VAF 39/42 reads (93%) | called by muse, mutect2, varscan2
